Surgical pathology report (de-identified scan), TCGA case TCGA-MB-A5Y8, project TCGA-SARC (Sarcoma), tissue source site University of Minnesota, specimen TCGA-MB-A5Y8-01A (Primary Tumor).

[page 1 of 3]
Collected:

Received:

Reported:

path ICD-O-3
Histocytoma, fibrous malignant
CSF 8830/3
Sarcoma, Undifferentiated pleomorphic
8805/3
Site: Connective, subcutaneous and
other soft tissues of calf
C49.2
JH 4/29/13

INTERPRETATION:

ADDENDUM:

Additional sections of the deep margin from Part A of this case were submitted in blocks A11 and A12. The deep margin is negative for tumor.

ORIGINAL REPORT:

SPECIMEN(S):

A: Sarcoma, right posterior calf

B: Medial subcutaneous margin #2

C: Medial tendon margin #2

FINAL DIAGNOSIS:

A. Skin and soft tissue, posterior right calf (excision of tumor):

- Malignant fibrous histiocytoma (12.8 x 3.5 x 2.5 cm) involving the subcutaneous soft tissue.
- Angiolymphatic invasion is identified
- The tumor extends to within less than 1 mm of the medial margin of the specimen.

B. Soft tissue, posterior right calf, medial/subcutaneous margin #2

[page 2 of 3]
(biopsy):

- Negative for tumor.

C. Soft tissue, posterior right calf, medial tendon margin #2 (biopsy):

- Negative for tumor.

I have personally reviewed all specimens and or slides, including the listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

The patient is a -year-old female with a history of sarcoma, right calf.

GROSS:

Three formalin-filled containers are received, each labeled with the patient's name, and hospital identification number.

A. The first container is additionally labeled, "A-right posterior calf sarcoma and received fresh for frozen section," and consists of an 8.5 x 4.6 x 3.2 cm portion of fibroadipose tissue, which is focally covered by a 9.5 x 2.5 cm white skin tissue on the surface. The skin surface is white, smooth, and unremarkable. The specimen is

[page 3 of 3]
oriented with a long double stitch at 9:00-medial margin, and a long single stitch at 6:00-distal margin. The specimen is inked as follows: 12-3-6:00 in blue, 6-9-12:00 in black. Sectioning reveals a 12.8 x 3.5 x 2.5 cm light red-yellow, firm, lobulated and well-defined mass within subcutaneous tissue. The mass measures 0.1 cm to the closest 9:00 margin. The remaining margins are grossly free of tumor. Grossly, the skin is not involved by the mass. Representative sections are procured for potential future studies. A representative section of the mass with medial margin is submitted for frozen section and remnant. AFS1 - mass with medial margin, A2 - 12:00 (proximal) tip, A3 - 6:00 (distal) tip, A4 and A5 - mass with medial margin, A6 - mass with lateral margin, A7 through A10 - mass.

B. The second container is additionally labeled, "B-medial/subcutaneous margin #2, right posterior calf" and consists of a 1.5 x 1.0 x 0.4 cm yellow lobulated soft adipose tissue. Entirely submitted in B1.

C. The next container is additionally labeled, "C-medial tendon margin #2, right posterior calf," and consists of a 1.7 x 0.5 x 0.3 cm white red soft tendinous tissue. Entirely submitted in C1.

MICROSCOPIC:

Microscopic evaluation is performed.

Source: NCI Genomic Data Commons file 2c102f36-6ba2-44cf-ae81-3be9f998eb22 (TCGA-MB-A5Y8.9F8975AF-457C-43C6-805F-88522CA1A5A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).